Surgical pathology report (de-identified scan), TCGA case TCGA-MT-A7BN, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Minnesota, specimen TCGA-MT-A7BN-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN(S):

- A: Posterior skin
- B: Subdermal mass, under flap by external jugular
- C: Posterior parotid perifacial node
- D: Greaure auricular
- E: Paratid Superior margin of tumor
- F: Right parotidectomy
- G: Upper deep margin
- H: Lower deep margin
- I: Inferior skin margin
- J: Anterior skin margin
- K: Superior skin margin
- L: Ear lobe skin margin
- M: Zone 3 lymph node
- N: Neck dissection: Lateral zones 2 and 3
- O: Anterior zones 2A and 3
- P: Submandibular gland, right

FINAL DIAGNOSIS:

- A. Posterior skin, excision:
- Squamous mucosa, negative for carcinoma
- B. Subdermal mass, under flap by external jugular, excision:
- One lymph node, negative for carcinoma (0/1)
- C. Posterior parotid perifacial node, excision:
- One lymph node, negative for carcinoma (0/1)
- D. Greaure auricular, excision:

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site ^{oral}
Floor of mouth NOS
C04.9

^{path}
Parotid gland
C07.9

Jan 8/27/13

[page 2 of 3]
- Fibroconnective tissue, negative for carcinoma

E. Parotid superior margin of tumor, excision:

- Benign salivary gland tissue
- No evidence of carcinoma

F. Right parotid, right parotidectomy:

- Invasive squamous cell carcinoma, poorly differentiated, greater than 5.0 cm
- Resection margin: Negative for carcinoma. The invasive carcinoma

is 0.1 cm from the closest resection margin.

- No squamous cell carcinoma in situ identified
- Benign salivary glands
- See comment

G. Upper deep margin, excision:

- Benign salivary gland tissue, negative for carcinoma

H. Lower deep margin, excision:

- Benign salivary gland tissue, negative for carcinoma

I. Inferior skin margin, excision:

- Squamous mucosa, negative for carcinoma

J. Anterior skin margin, excision:

- Squamous mucosa, negative for carcinoma

K. Superior skin margin, excision:

- Squamous mucosa, negative for carcinoma

L. Ear lobe skin margin, excision:

- Squamous mucosa, negative for carcinoma

M. Zone 3 lymph node, excision:

- One lymph node, negative for carcinoma (0/1)

[page 3 of 3]
N. Neck dissection: Lateral zones 2 and 3, excision:

- Thirteen lymph nodes, negative for carcinoma (0/13)

O. Anterior zones 2A and 3, excision:

- One of three lymph nodes with metastatic poorly differentiated squamous cell carcinoma (0.6 cm in length) (1/3)

- Extranodal extension: Absent

P. Submandibular gland, right, excision:

- Benign salivary gland tissue, negative for carcinoma

COMMENT:

Invasive poorly differentiated squamous cell carcinoma (greater than 5.0 cm) is identified in the parotid glands. No squamous cell carcinoma in situ is seen. The invasive squamous cell carcinoma could be from the overlying skin, metastatic from other organs or primary tumor from parotid.

However, primary parotid squamous cell carcinoma is very uncommon.

Correlation with complete clinical information is required.

Reviewed CT + PET scan 1 wk prior to this surgery. No other tumors/lesions noted. PET scan states:

CLINICAL HISTORY:

The patient has right parotid cancer.

parotid high-grade malignancy.

Operative Procedure: Right parotidectomy with radical neck dissection and margins. Multiple frozen sections.

BCK

Qual/Syncronous Primary Noted		☒
Reviewer Initials	BTA	Reviewed 8/13/13

Source: NCI Genomic Data Commons file 455009f0-def0-4b90-8ea9-68663241853c (TCGA-MT-A7BN.BEDF059B-CFDA-4B9C-A9A3-1737D814910B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).